Somatic mutation profile of tumor specimen TCGA-06-0750-01A (aliquot TCGA-06-0750-01A-01D-1492-08) from TCGA case TCGA-06-0750, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.9 years (16,018 days).
Specimen TCGA-06-0750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35e51960-83bf-4367-9e8b-21456ae5bb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0750-10A (Blood Derived Normal), aliquot TCGA-06-0750-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe25ecca-4ea3-4aa8-a573-6eade92b5b45

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 4, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 369/2703 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 450/2658 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, varscan2
- EGFR | c.1787C>G p.P596R | Missense Mutation (SNP) | VAF 792/3482 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51779162, COSV51807036; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 29/86 reads (34%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- ARHGAP26 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.584); catalogued as rs148543665; called by muse, mutect2, varscan2
- BPGM | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as rs759610083, COSV61324339; called by muse, mutect2, varscan2
- BPIFB3 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs199722228, COSV64956789; called by muse, mutect2, varscan2
- CHSY1 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 26/200 reads (13%) | catalogued as COSV54253856; called by muse, mutect2, varscan2
- CRYBG2 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs201302371; called by muse, mutect2, varscan2
- DMD | c.1142C>G p.T381S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV55876821; called by muse, mutect2, varscan2
- DPEP1 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55360593; called by muse, mutect2, varscan2
- FSTL4 | c.2280C>A p.D760E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV54773300; called by muse, mutect2, varscan2
- FXR2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs778721641, COSV51468462; called by muse, mutect2, varscan2
- GABRA5 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59480694; called by muse, mutect2, varscan2
- GGT5 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs149456868; called by muse, mutect2, varscan2
- GPR17 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV55755546; called by muse, mutect2, varscan2
- KLHL20 | c.1601G>T p.W534L | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942430; called by muse, mutect2, varscan2
- MAP1S | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV60723023; called by muse, mutect2, varscan2
- MC4R | c.610A>T p.M204L | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV55352265; called by muse, mutect2, varscan2
- NPEPPS | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs756003607, COSV59102938; called by muse, mutect2, varscan2
- NR1H4 | c.299G>A p.R100H (on ENST00000551379 / NM_001206993.2; = p.R90H on NM_005123.4) | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs113431969, COSV51850072, COSV51850512, COSV51856383; called by muse, mutect2, varscan2
- OR5P2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs765255136, COSV61490080; called by muse, mutect2, varscan2
- PCDH11Y | c.2881A>G p.K961E (on ENST00000400457 / NM_032973.2; = p.K950E on NM_032971.3) | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53082649; called by muse, mutect2, varscan2
- PDE2A | c.1807T>C p.F603L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV57808511; called by muse, mutect2, varscan2
- PHF20 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV59186108, COSV59186517; called by muse, mutect2, varscan2
- PHLDA2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV56540359; called by muse, mutect2, varscan2
- RBFA | c.178A>C p.S60R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV51534085; called by muse, mutect2, varscan2
- SLC14A2 | c.522G>T p.R174S | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV54909803; called by muse, mutect2, varscan2
- SLC34A3 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs138798032; called by muse, mutect2, varscan2
- SNX14 | c.1111G>T p.E371* (on ENST00000314673 / NM_001350535.1; = p.E327* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59012974; called by muse, mutect2, varscan2
- SRPRA | c.1651G>T p.G551* | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV55007092; called by muse, mutect2, varscan2
- SYDE2 | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.467); catalogued as COSV52315970, COSV99320237; called by muse, mutect2, varscan2
- ZFC3H1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV57348842; called by muse, mutect2, varscan2
- ZNF98 | c.1575A>T p.K525N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV63337019; called by muse, mutect2, varscan2
- AMER3 | c.2064C>T p.N688= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs763951703, COSV58467051; called by muse, mutect2, varscan2
- DSG1 | c.2505C>T p.V835= | Silent (SNP) | VAF 56/384 reads (15%) | catalogued as rs1161355068, COSV57136190; called by muse, mutect2, varscan2
- FKBP10 | c.738C>T p.I246= | Silent (SNP) | VAF 71/229 reads (31%) | catalogued as rs573865037, COSV58637000; called by muse, mutect2, varscan2
- OR52J3 | c.654G>A p.S218= | Silent (SNP) | VAF 114/333 reads (34%) | catalogued as rs148600962, COSV66747742; called by muse, mutect2, varscan2
- OR5W2 | c.741G>A p.A247= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs547924373, COSV100747702, COSV60616456; called by muse, mutect2, varscan2
- SCNN1D | c.603C>T p.S201= (on ENST00000338555; = p.S365= on NM_001130413.4) | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV57641890; called by muse, mutect2, varscan2
- TMEM144 | c.156C>G p.A52= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as COSV56701340; called by muse, mutect2, varscan2
- TMPRSS3 | c.744G>A p.T248= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs369903582; called by muse, mutect2, varscan2
- CST7 | c.-50C>A | 5'UTR (SNP) | VAF 46/145 reads (32%) | catalogued as COSV65195818; called by muse, mutect2, varscan2
